Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9L0, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9L0-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
~~Adenocarcinoma~~ NOS 8140/3
Site Prostate NOS C61.9
JW 1/23/14

Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 69 g, Volume: 64 ml, Size: 5 x 6 x 4.5 cm. Adherent seminal vesicles and deferent duct: right side: 5 cm, left side: 2 cm. The surface is marked with green ink on the right side, blue ink on the left side. Apical peri-urethral a funnel shaped 0.8 x 0.5 cm tissue defect marked with red ink. Total of the cross sections: 1.5 cm.
2. (Lymph nodes, right side): 4.5 x 2.5 x 2 cm measuring adipose tissue containing 8 nodes measuring up to 3.5 x 1.2 x 0.5 cm.
3. (Lymph nodes, left side): 5 x 4 x 2 cm measuring adipose tissue containing 6 nodes measuring up to 2.5 x 1.5 x 0.8 cm.

Microscopy:

1. Apex right and left: Right 10 tissue blocks, left 6 tissue blocks (total 16 tissue blocks). 3 cross sections: Right 19 tissue blocks, left 19 tissue blocks (total 38 tissue blocks). Basis right and left: Right 22 tissue blocks, left 12 tissue blocks (total 34 tissue blocks). Seminal vesicles right and left: Right 5 tissue blocks, left 4 tissue blocks (total 9 tissue blocks).
2. Frozen lymph nodes right: 10 tissue blocks.
3. Frozen lymph nodes left: 10 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 70%, Gleason 4: 28%, Gleason 3: 2%). Tumor involves both lobes with main focus on the right side. Maximum tumor diameter: 45 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 7 non-adjacent tissue blocks (maximum invasion length 2.8 mm, maximal invasion depth 2.3 mm). Tumor infiltration of both seminal vesicles. Positive surgical margin in 12 blocks with main focus on the circumferential right side and around the right seminal vesicle (contact area: 12.0 x 11.0 mm; Gleason 5 and 4). Tumor-free peri-urethral resection margin.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia.

2. (Lymph nodes, right side): One lymph node metastasis (0.7 mm without extracapsular invasion) in a total of six lymph nodes (1/6).

[page 2 of 2]
3. (Lymph nodes, left side): Five lymph node metastases (up to 22 mm with partial extracapsular invasion) in a total of thirteen lymph nodes (5/13).

Tumor classification

(in consideration of the intraoperative frozen-section, parallel report and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 70%, Gleason 4: 28%, Gleason 3: 2%), maximum tumor diameter: 45 mm, tumor volume approx. 28.2 ml (Gleason 5: 19.7 ml, Gleason 4: 7.9 ml, Gleason 3: 0.6 ml), pN1 (7/20), L0*, V0, R1

Comments:

Positive surgical margin in tissue blocks R1C, R2C, R2D, R3D, L3D, BR1A, BR2A, SBR1, SBR2, SBR4, SBR5 and SBL3.

Tumor infiltration of seminal vesicles on both sides in tissue blocks RP3, SBR1, SBR2, SBR3, SBR5, BL2C and SBL3.

Tumor infiltration into peri-prostatic adipose tissue in tissue blocks AR3B, BL1C, BL3B, SBL1, A1, A2, and B1.

In the preceding intraoperative frozen section an additional lymph node metastasis of prostatic adenocarcinoma was found (1/1).

Additional immunohistochemical analyses (D2-40, CD 31) on tissue blocks SBR1 and SBR2 revealed no lymphatic or venous invasion. *Despite the fact that no lymphatic or venous invasion was assessed, it has to be assumed that at the point of lymph node metastasis L1 was present.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 12d29d5f-3bc2-40a8-b514-f4cf5c3bdef2 (TCGA-ZG-A9L0.F5D6CACB-458D-4C16-972E-EF6848DEC4D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).